Gene-level copy-number profile of tumor specimen TCGA-LN-A49U-01A from TCGA case TCGA-LN-A49U, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 62.9 years (22,969 days).
Specimen TCGA-LN-A49U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.631dbac1-235a-423d-b657-3e930febb942.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9f5e246e-8a91-4ef7-a3b3-96ea9dd7273c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 9,245; copy number 2: 36,498; copy number 3: 13,080; copy number 4: 733; copy number 5: 95; copy number 6: 68; copy number 7: 4; copy number 9: 88.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A49U-01A-31D-A25X-01): tumor purity 0.76, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:20,728,606–21,948,772, 1 gene (within-gene range 0–1): KCNIP4.
- chr4:21,304,468–21,719,026, 6 genes: AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2.
- chr4:86,117,912–86,219,926, 1 gene: MAPK10-AS1.
- chr4:125,507,259–125,507,307, 1 gene: MIR2054.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 255 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:17,684,584–25,701,324, 72 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:77,416,673–77,640,069, 4 genes, copy number 7 (within-gene range 3–7): AC004921.1, GCNT1P5, AC004921.2, PTPN12.
- chr9:30,388,935–30,800,746, 6 genes, copy number 5–6: LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36.
- chr10:12,195,965–12,328,389, 3 genes, copy number 5: CDC123, AL512770.1, RN7SL198P.
- chr10:12,415,928–12,456,631, 2 genes, copy number 5: AL391314.1, RNU6ATAC39P.
- chr17:62,699,244–63,427,699, 15 genes, copy number 5 (within-gene range 2–5): AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3, AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2, TANC2, AC006270.2, AC006270.1, DNAJB6P8, AC015923.1.
- chr18:976,589–5,004,537, 65 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr19:57,664,280–58,605,223, 88 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,824. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
